Surgical pathology report (de-identified scan), TCGA case TCGA-61-1906, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1906-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY –

POSITIVE FOR METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA.

PART 2: APPENDIX, APPENDECTOMY –

POSITIVE FOR METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVING THE MESOAPPENDIX AND THE APPENDEAL WALL.

PART 3: UTERUS, CERVIX AND BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY (290 GRAMS) –

- A. POORLY PAPILLARY SEROUS ADENOCARCINOMA OF BOTH OVARIES (RIGHT 15.0 CM; LEFT 8.5 CM) WITH EXTRACAPSULAR EXTENSION, OVARIAN SURFACE INVOLVEMENT AND EXTENSIVE LYMPHOVASCULAR INVASION.
- B. FALLOPIAN TUBES WITH METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVING MESOSALPINX AND FALLOPIAN TUBES WALLS.
- C. METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVES THE UTERINE SEROSA WITH EXTENSIVE LYMPHOVASCULAR INVASION OF THE MYOMETRIUM AND CERVICAL STROMA.
- D. ATROPHIC ENDOMETRIUM WITH CYSTIC CHANGES OF THE GLANDS.
- E. ENDOMETRIAL POLYP WITH CYSTIC CHANGES OF THE GLANDS.
- F. LEIOMYOMATA (1.5 CM, 2.0 CM).
- G. CHRONIC CERVICITIS.

PART 4: SIGMOID TUMOR, RESECTION –

POSITIVE FOR METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA.

PART 5: LYMPH NODE, RIGHT GROIN, EXCISION –

POSITIVE FOR METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA IN ONE OF ONE RIGHT GROIN LYMPH NODE (1/1).

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 15 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Papillary (2)
CYTOLOGIC ATYPIA:	Marked (3)
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Uterus, Omentum
SURFACE IMPLANT SIZE:	> 2 cm.
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 1
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 1
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT3c
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIIC

Source: NCI Genomic Data Commons file cb9de84f-0e43-4954-bc3d-849c930b0971 (TCGA-61-1906.A540B6E3-4A34-4546-A91A-A6BCD09921BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).